Gene-level copy-number profile of specimen HCM-CSHL-0081-C25-85B from HCMI case HCM-CSHL-0081-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 57.9 years (21,139 days).
Specimen HCM-CSHL-0081-C25-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 265b0f8c-87d3-4bd4-b5e8-89d4adc31fe6.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0081-C25-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,875 have no estimate.
https://portal.gdc.cancer.gov/files/dcb3994f-0b26-4a64-979a-b0467b3d693a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 301; copy number 1: 17; copy number 2: 10,432; copy number 3: 4,147; copy number 4: 40,194; copy number 5: 1,850; copy number 6: 108; copy number 7: 1,536; copy number 8: 25; copy number 9: 11; copy number 10: 101; copy number 17: 2; copy number 18: 5; copy number 19: 4; copy number 58: 8; copy number 103: 7.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:22,203,990–22,214,672, 1 gene: AL157937.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 138 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:56,521,820–58,105,935, 89 genes, copy number 10 (broad region; genes not listed).
- chr12:59,596,029–59,812,576, 3 genes, copy number 9: SLC16A7, AC079905.2, AC079905.1.
- chr12:61,600,067–62,279,150, 4 genes, copy number 9 (within-gene range 3–9): DUX4L52, TAFA2, RPL21P104, KRT8P19.
- chr12:66,302,493–67,670,919, 16 genes, copy number 9–10: HELB, GRIP1, OSBPL9P5, OSBPL9P4, AC073530.1, AC073530.2, RAB11AP2, GGTA2P, CAND1, MRPL40P1, NTAN1P3, LINC02420, LINC02408, LINC02442, DYRK2, AC078777.1.
- chr12:69,359,710–70,637,440, 26 genes, copy number 17–103: YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL, PRANCR, AC078922.1, LINC02821, AC092881.2, CNOT2, AC092881.1, KCNMB4, RNU4-65P, AC025569.1, PTPRB, AC083809.1.

Autosomal genes at a single copy (total copy number 1): 17. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
